Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4640, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4640-01A (Primary Tumor).

Pathology Accession

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (60% CLEAR CELLS AND 40% EOSINOPHILIC CELLS),

FUHRMAN'S NUCLEAR GRADE 4.

TUMOR EXTENDS INTO RENAL VEIN.

TUMOR MEASURES 9.0 CM IN MAXIMUM DIMENSION.

NO UNEQUIVOCAL EXTENSION INTO PERINEPHRIC ADIPOSE TISSUE IDENTIFIED.

Vascular, ureteral, and soft tissue margins free of tumor.

Adrenal gland, no tumor present.

TCGA - CJ - 4640

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A radical nephrectomy specimen (26.0 x 11.0 x 7.5 cm), with segments of renal artery, renal vein and ureter (3.0 cm in length and 0.6 cm in average diameter) and adrenal gland (5.5 x 2.5 x 0.5 cm).

There is a 9.0 x 6.5 x 6.0 cm well-circumscribed tumor centered in the middle of the kidney, replacing two-thirds of the renal parenchyma. The tumor is white with friable areas and hemorrhage. The tumor bulges into renal vein (1.0 cm from the margin), and appears to invade the renal sinus and the perirenal fat, but not reaching the Gerota's fascia. The tumor does not involve the renal pelvis.

The adjacent renal parenchyma is unremarkable. No hilar lymph nodes are identified. The adrenal gland has unremarkable cortex and medulla.

Tumor and normal tissue have been submitted for possible electron microscopy and tumor bank.

INK CODE: Blue - Gerota's fascia.

SECTION CODE: A1, ureteral, renal vein and artery margins; A2, tumor in renal vein; A3-A5, tumor in renal sinus; A6, tumor and renal pelvis; A7-A9, upper part of tumor with soft tissue margin; A10, tumor with renal parenchyma; A11, A12, lower part of tumor with soft tissue margin; A13, normal renal parenchyma; A14, adrenal gland.

CLINICAL HISTORY

Left renal mass.

Source: NCI Genomic Data Commons file 37ed44a4-7782-4e27-bc8d-01cd637afb52 (TCGA-CJ-4640.8780608C-344A-4369-8003-3053B91F6B55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).